TCGA case TCGA-2G-AAH0 — Testicular Germ Cell Tumors (TCGA-TGCT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Germ Cell Neoplasms; Primary site: Testis; Tissue source site: Erasmus MC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d0f2103b-a525-4ab4-a476-df21623e756c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Netherlands; Age at index: 30 years; Year of birth: 1969; Vital status: Alive.

Diagnoses (2)
1. Seminoma, NOS (the primary disease): ICD-O-3 morphology code: 9061/3; ICD-10 code: C62.9; Tissue or organ of origin: Testis, NOS; Site of resection or biopsy: Testis, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 30.5 years (11,123 days); Year of diagnosis: 1999; Method of diagnosis: Orchiectomy; AJCC staging edition: 5th; AJCC clinical T: T2; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IS; AJCC pathologic T: T2; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage IS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 5,477 days (15.0 years); Ajcc serum tumor markers: S1.
   Pathology details: Lymph node dissection site: Retroperitoneal; Lymph nodes removed: No; Timepoint category: Postoperative.
   Pathology details: Intratubular germ cell neoplasia present: No; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bleomycin + Cisplatin + Etoposide; Treatment intent type: Adjuvant; Days to treatment start: 122 days; Days to treatment end: 179 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Seminoma, NOS), site: Intra-abdominal lymph nodes. Age at diagnosis: 30.7 years (11,230 days); Days to diagnosis: 107 days; Prior treatment: Yes.

Follow-up (4 entries)
- Day 107 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Intra-abdominal lymph nodes; Days to recurrence: 107 days.
- Days to follow up: 1,833 days (5.0 years); Disease response: Tumor Free.
- Days to follow up: 5,477 days (15.0 years); Disease response: Tumor Free.
- Karnofsky performance status: 100; ECOG performance status: 0; Timepoint: Follow-up.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day -2: Lactate Dehydrogenase 313; Alpha Fetoprotein 22; Human Chorionic Gonadotropin 5.1.
- Day 18: Lactate Dehydrogenase 305; Alpha Fetoprotein 3.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Fertility history: Conceived 1 or more children by natural conception; Undescended testis history: No.

Family history
- Relative with cancer history: yes; Relationship type: Natural Mother; Relationship primary diagnosis: Lymphoma.
- Relative with cancer history: yes; Relationship type: Uncle; Relationship primary diagnosis: Testicular Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-2G-AAH0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 210 mg.
  Slide TCGA-2G-AAH0-01A-01-TS1: Section location: Top; Percent tumor cells: 93; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 7; Percent stromal cells: 0; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-2G-AAH0-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-2G-AAH0-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; History hypospadias: No; History fertility: Fathered > or = 1 child by natural conception; Tumor status: Tumor free.
- Stage record: AJCC pathologic tumor stage: IS.
- Primary pathology: Submitted tumor site: Testes; Testis tumor macroextent: Involves testis only; Intratubular germ cell neoplasm: Absent; Lymphovascular invasion: Yes; Post orchi lymph node dissection: No; First treatment success: No Measureable Tumor or Tumor Markers.
- Primary pathology, Histology list, Histology 1: Histologic diagnosis: Seminoma, NOS; Histologic diagnosis percent: 95.
- Primary pathology, Histology list, Histology 2: Histologic diagnosis: Non-Seminoma, Embryonal Carcinoma; Histologic diagnosis percent: 5.
- Primary pathology, Pre orchi serum marker info: Pre orchi LDH: 313; Pre orchi hcg: 5.1; Pre orchi afp: 22.
- Primary pathology, Post orchi serum marker info: Post orchi LDH: 305; Post orchi afp: 3.
- Primary pathology, Molecular test result list: Molecular test result: Lactate Dehydrogenase (LDH) - Normal; Molecular test result: Human Chorionic Gonadotropin (HCG) - Normal; Molecular test result: Alpha Fetaprotein (AFP) - Normal.
- Follow-up form 1: Lost to follow-up: No; Post orchi lymph node dissection: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response.
- Follow-up form 2: Lost to follow-up: No; Post orchi lymph node dissection: No; Tumor status: Tumor free; Treatment outcome first course: No Measureable Tumor or Tumor Markers.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 5,477 days; disease-specific survival: no event (censored), 5,477 days; disease-free interval: event (new tumor event after initially disease-free), 107 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 107 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-2G-AAH0-01A-11D-A42X-01): tumor purity 0.46, ploidy 3.24, whole-genome doublings 1.
